Gene-level copy-number profile of tumor specimen TCGA-VD-A8KF-01A from TCGA case TCGA-VD-A8KF, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Overlapping lesion of eye and adnexa; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.6 years (25,066 days).
Specimen TCGA-VD-A8KF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.83e9b1fe-649e-4de4-b6f3-aacd38343dfb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VD-A8KF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ee67721-1e23-4a82-bb5c-601d9c0a8abd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,553; copy number 2: 48,719; copy number 3: 4,548.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VD-A8KF-01A-11D-A39V-01): tumor purity 1, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,132. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
